Gene-level copy-number profile of tumor specimen TCGA-AA-A02H-01A from TCGA case TCGA-AA-A02H, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 74.9 years (27,362 days).
Specimen TCGA-AA-A02H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.038e3b19-1928-4872-b557-eea8e8f02332.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A02H-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/27f47656-02b1-47a1-a981-e6df03874df5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 800; copy number 2: 13,241; copy number 3: 36,872; copy number 4: 5,203; copy number 5: 2,333; copy number 7: 404; copy number 8: 895; copy number 34: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-A02H-01A-01D-A008-01): tumor purity 0.73, ploidy 2.98, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:236,194,872–236,264,409, 2 genes (within-gene range 0–3): ASB18, RNU1-31P.
- chr7:155,003,448–155,005,703, 1 gene: PAXIP1-AS1.
- chr9:98,798,466–98,807,564, 1 gene: AL807776.1.
- chr9:120,855,651–120,894,896, 1 gene (within-gene range 0–3): PHF19.
- chr10:1,361,001–1,361,637, 1 gene: AL513304.1.
- chr10:28,522,652–28,533,066, 1 gene (within-gene range 0–3): WAC-AS1.
- chr11:17,013,998–17,053,024, 1 gene (within-gene range 0–3): OR7E14P.
- chr11:17,385,859–17,389,331, 1 gene: KCNJ11.
- chr11:23,403,805–23,406,103, 1 gene: WIZP1.
- chr11:135,061,781–135,075,908, 1 gene: LINC02684.
- chr12:120,904,702–120,915,123, 2 genes: AC069214.1, CLIC1P1.
- chr18:4,459,230–4,459,458, 1 gene: ELOCP27.
- chr22:46,255,663–46,263,343, 1 gene: PKDREJ.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,350 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:26,755,200–28,778,937, 51 genes, copy number 34: GPR12, FGFR1OP2P1, AL160035.1, RPS21P8, RPS20P32, USP12, AL158062.1, USP12-AS1, USP12-AS2, LINC02340, LINC00412, RPL21, SNORD102, SNORA27, RASL11A, RNU6-70P, LINC01079, RNY1P1, GTF3A, MTIF3, RNU6-63P, LNX2, POLR1D, AL136439.1, NPM1P4, GSX1, PLUT, RNU6-73P, PDX1, ATP5F1EP2, LINC00543, CDX2, URAD, RN7SL272P, FLT3, KATNBL1P1, CHCHD2P8, PAN3-AS1, PAN3, EEF1A1P3, RNU6-82P, FLT1, AL139005.1, EIF4A1P7, Y_RNA, POMP, SLC46A3, RNU6-53P, CYP51A1P2, AL359741.1, POM121L13P.
- chr13:84,867,514–114,337,626, 404 genes, copy number 7 (broad region; genes not listed).
- chr20:30,294,550–58,161,150, 692 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr20:58,228,940–64,313,132, 203 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 800. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
